CCDI case PBCCTU — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/c5163944-d123-4513-92a0-e0281ddbd53f

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Ependymoma, NOS: ICD-O-3 morphology code: 9391/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 2.8 years (1,036 days).

Biospecimens (3 samples)
- Sample 0DOLUV: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DOLVD: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
- Sample 0DOLW1: Tissue type: Tumor; Specimen type: Solid Tissue.
